Somatic mutation profile of tumor specimen TARGET-10-PAPDUX-09A (aliquot TARGET-10-PAPDUX-09A-01D) from TARGET case TARGET-10-PAPDUX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,359 days).
Specimen TARGET-10-PAPDUX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b58d801-246f-4114-af6d-6e6307b3a514.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPDUX-14A (Bone Marrow Normal), aliquot TARGET-10-PAPDUX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bdd0b13-f27e-4615-a5d1-499474b145ba

The open-access MAF lists 26 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 5, Silent 3, Frame Shift Ins 3, Frame Shift Del 1, In Frame Del 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CA6 | c.659C>G p.T220S | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs757686926; called by muse, mutect2
- COL3A1 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.431); catalogued as rs762028131, COSV58584897; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGF3 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.984); catalogued as rs1408695395; called by muse, mutect2, varscan2
- LZTR1 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1358951592, COSV53149045; called by muse, mutect2
- OR10G3 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs200597674, COSV57809974; called by muse, mutect2, varscan2
- PRDM10 | c.3125C>T p.S1042F | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.203); catalogued as rs1400273941, COSV100457012; called by muse, mutect2, varscan2
- ADGRV1 | c.15508C>G p.L5170V | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGFG1 | c.581dup p.K195Efs*4 | Frame Shift Ins (INS) | VAF 18/128 reads (14%) | called by mutect2, pindel, varscan2
- FOXP2 | c.480_494del p.Q187_Q191del | In Frame Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, varscan2
- OR2A2 | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 27/350 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- PAX5 | c.622_623insCGCCG p.V208Afs*72 | Frame Shift Ins (INS) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- PROS1 | c.1754A>G p.E585G | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SLC9C2 | c.597del p.F199Lfs*19 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | called by mutect2, varscan2
- TANC2 | c.2309_2310insCA p.W770Cfs*36 | Frame Shift Ins (INS) | VAF 30/83 reads (36%) | called by mutect2, pindel*, varscan2
- TRPV6 | c.298G>C p.A100P | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.637); called by muse, mutect2
- TTC6 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CAMTA1 | c.3009C>T p.S1003= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1431634664, COSV100351529; called by muse, varscan2
- CCNB3 | c.3831G>A p.K1277= | Silent (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
- CPNE2 | c.885C>T p.S295= | Silent (SNP) | VAF 25/126 reads (20%) | called by muse, mutect2, varscan2
- CUL4B | c.68-821C>T | Intron (SNP) | VAF 7/14 reads (50%) | catalogued as rs1457746075; called by mutect2, varscan2
- MED21 | c.*1621del | 3'UTR (DEL) | VAF 6/48 reads (13%) | catalogued as rs1469619431; called by mutect2, varscan2
- MRC2 | c.2437+48G>A | Intron (SNP) | VAF 28/130 reads (22%) | catalogued as rs1040300534; called by muse, mutect2, varscan2
- PDE4DIP | c.2904+1629C>T | Intron (SNP) | VAF 13/34 reads (38%) | called by mutect2, varscan2
- RN7SL176P | chr12:100158024 C>T | 3'Flank (SNP) | VAF 21/86 reads (24%) | catalogued as rs764813996; called by muse, mutect2, varscan2
- VOPP1 | c.54+10262C>T | Intron (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- ZNF532 | c.3263+25G>A | Intron (SNP) | VAF 23/66 reads (35%) | catalogued as rs538928226; called by muse, mutect2, varscan2
